Somatic mutation profile of tumor specimen C3N-00380-01 (aliquot CPT0021240009) from CPTAC case C3N-00380, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.3 years (20,938 days).
Specimen C3N-00380-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1499c378-be71-40c7-b0bd-289503c2476c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00380-71 (Blood Derived Normal), aliquot CPT0021300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43e565df-7358-4c43-ba70-ecffe484acfb

The open-access MAF lists 85 somatic variants for this specimen: 60 protein-altering or splice-affecting, 17 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 17, Intron 6, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 3, Frame Shift Ins 2, Splice Region 1, 3'UTR 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 58/271 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs5030826, CM941362, CM941363, CM941364, COSV56543026, COSV56543035, COSV56543220, COSV56562588; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM19 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs768825848, COSV99976298; called by muse, mutect2, varscan2
- AKAP13 | c.2890C>G p.H964D | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.021); catalogued as COSV63464959; called by muse, mutect2, varscan2
- BRCA2 | c.8004A>C p.R2668S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); catalogued as rs777675936; called by muse, mutect2, varscan2
- CCER1 | c.818C>G p.P273R | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV62645800; called by muse, mutect2, varscan2
- DAGLA | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as COSV57197210; called by muse, mutect2, varscan2
- HCFC1 | c.4135G>A p.D1379N | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs782655422; called by muse, mutect2, varscan2
- HNRNPUL2 | c.539-2A>G p.X180_splice | Splice Site (SNP) | VAF 24/125 reads (19%) | catalogued as rs111417415; called by muse, mutect2, varscan2
- MAP2 | c.1957A>C p.S653R | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180769033; called by muse, mutect2, varscan2
- MEIS3 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs572224868; called by muse, mutect2, varscan2
- NRDE2 | c.1714A>G p.K572E | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV62962170; called by muse, mutect2, varscan2
- PHF10 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as rs1260148004; called by muse, mutect2, varscan2
- RDX | c.1564G>T p.E522* | Nonsense Mutation (SNP) | VAF 35/182 reads (19%) | catalogued as COSV100563121; called by muse, mutect2, varscan2
- SIGLEC12 | c.1072C>T p.R358* (on ENST00000291707 / NM_053003.4; = p.R240* on NM_033329.2) | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as rs755724495, COSV52460192, COSV52462310; called by muse, mutect2, varscan2
- SMG5 | c.2204G>C p.R735P | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.966); catalogued as COSV62437654; called by muse, mutect2
- SNRNP40 | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as rs953836038; called by muse, mutect2, varscan2
- SOX6 | c.916del p.Q306Sfs*34 (on ENST00000528429 / NM_001145819.2; = p.Q306Sfs*57 on NM_017508.3) | Frame Shift Del (DEL) | VAF 71/518 reads (14%) | catalogued as COSV100323041; called by mutect2, pindel, varscan2
- SPG11 | c.2509G>T p.D837Y | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs762708084; called by muse, mutect2, varscan2
- STIL | c.45G>A p.R15= | Splice Region (SNP) | VAF 24/163 reads (15%) | catalogued as rs1481508593; called by muse, varscan2
- TACC1 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as rs760362705; called by muse, mutect2, varscan2
- UNC79 | c.5836C>G p.Q1946E (on ENST00000393151 / NM_001346218.2; = p.Q1769E on NM_020818.5) | Missense Mutation (SNP) | VAF 50/350 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs376392862; called by muse, mutect2, varscan2
- ABCF1 | c.1907G>T p.G636V (on ENST00000326195 / NM_001025091.2; = p.G598V on NM_001090.3) | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- CACHD1 | c.2297A>G p.N766S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CD44 | c.2112C>A p.S704R | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CHKA | c.1013_1016+1del p.X338_splice | Splice Site (DEL) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- CNNM3 | c.983A>T p.D328V | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- COL3A1 | c.2630C>T p.A877V | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- COPS6 | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CPB1 | c.148A>C p.I50L | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CYP2E1 | c.545A>G p.D182G | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- DCHS1 | c.5651C>A p.A1884D | Missense Mutation (SNP) | VAF 45/374 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DONSON | c.1472C>A p.S491* | Nonsense Mutation (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- EFCAB6 | c.4102A>G p.I1368V | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FABP3 | c.212dup p.D72Rfs*2 | Frame Shift Ins (INS) | VAF 17/108 reads (16%) | called by mutect2, pindel, varscan2
- FAM120C | c.353T>A p.V118E | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- FAM83G | c.1989G>T p.Q663H | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2
- GRIA3 | c.697-2A>T p.X233_splice | Splice Site (SNP) | VAF 26/220 reads (12%) | called by muse, varscan2
- GSTA2 | c.180T>G p.I60M | Missense Mutation (SNP) | VAF 51/370 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- HLF | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KCMF1 | c.1107G>C p.E369D | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- KRBA1 | c.2837C>A p.P946H | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- MICU1 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- MMP13 | c.1313del p.N438Mfs*51 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel, varscan2
- MRPL10 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH7 | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- NID2 | c.654G>T p.Q218H | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NINL | c.944T>A p.I315N | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- OR9G1 | c.127A>C p.T43P | Missense Mutation (SNP) | VAF 68/692 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.395); called by muse, mutect2
- PBRM1 | c.2116del p.M706Wfs*8 | Frame Shift Del (DEL) | VAF 27/94 reads (29%) | called by mutect2, pindel, varscan2
- PLIN4 | c.1408G>T p.V470F (on ENST00000301286; = p.V485F on NM_001367868.2) | Missense Mutation (SNP) | VAF 122/706 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RAPGEF1 | c.1684T>G p.S562A | Missense Mutation (SNP) | VAF 73/291 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RIOX2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- RXFP1 | c.2190_2195del p.E731_L732del | In Frame Del (DEL) | VAF 38/186 reads (20%) | called by mutect2, pindel, varscan2
- SATL1 | c.361C>A p.L121I (on ENST00000395409; = p.L308I on NM_001012980.2) | Missense Mutation (SNP) | VAF 98/477 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- SLC19A1 | c.1688G>C p.C563S | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SYMPK | c.2025_2026insACACA p.E676Tfs*29 | Frame Shift Ins (INS) | VAF 25/221 reads (11%) | called by mutect2, pindel
- TLN2 | c.4128G>T p.K1376N | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- UBA3 | c.475T>C p.F159L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- USH2A | c.10045A>T p.K3349* | Nonsense Mutation (SNP) | VAF 42/259 reads (16%) | called by muse, varscan2
- WDFY4 | c.7291T>C p.Y2431H | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ABCB4 | c.807C>T p.F269= | Silent (SNP) | VAF 89/543 reads (16%) | catalogued as rs1421517860, COSV99710648; ClinVar: likely benign; called by muse, mutect2, varscan2
- AMER3 | c.1362G>T p.G454= | Silent (SNP) | VAF 33/188 reads (18%) | catalogued as COSV58467881; called by muse, mutect2, varscan2
- ARHGAP4 | c.1899C>A p.R633= | Silent (SNP) | VAF 24/139 reads (17%) | called by muse, mutect2, varscan2
- COL22A1 | c.3468C>T p.G1156= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as rs1447054985, COSV57333640; called by muse, mutect2, varscan2
- ERN1 | c.2262G>T p.T754= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- GALNT2 | c.363C>T p.T121= | Silent (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2, varscan2
- INTS5 | c.3057G>T p.T1019= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100399852; called by muse, mutect2
- ITPRID2 | c.2475T>C p.H825= | Silent (SNP) | VAF 38/229 reads (17%) | catalogued as rs376425704; called by muse, mutect2, varscan2
- KIF1B | c.174T>G p.S58= | Silent (SNP) | VAF 56/305 reads (18%) | called by muse, mutect2, varscan2
- KIF2A | c.1110T>C p.Y370= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs1308917595; called by muse, mutect2, varscan2
- MYO18A | c.3408C>T p.H1136= | Silent (SNP) | VAF 59/359 reads (16%) | catalogued as rs375660360; called by muse, mutect2, varscan2
- PTCD2 | c.1038C>T p.T346= | Silent (SNP) | VAF 90/495 reads (18%) | called by muse, mutect2, varscan2
- SLC5A10 | c.1740T>C p.N580= (on ENST00000395645 / NM_001042450.4; = p.N596= on NM_152351.5) | Silent (SNP) | VAF 24/229 reads (10%) | called by muse, mutect2, varscan2
- TENT5C | c.552C>T p.F184= | Silent (SNP) | VAF 46/268 reads (17%) | catalogued as COSV65617122; called by muse, mutect2, varscan2
- TM4SF20 | c.162A>C p.G54= | Silent (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2, varscan2
- TSHZ1 | c.1893G>A p.P631= (on ENST00000580243 / NM_001308210.2; = p.P586= on NM_005786.6) | Silent (SNP) | VAF 24/223 reads (11%) | catalogued as rs145239521; called by muse, mutect2, varscan2
- USP3 | c.405A>G p.K135= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs757099582; called by muse, mutect2, varscan2
- ACSF3 | c.1367-46C>T | Intron (SNP) | VAF 106/625 reads (17%) | catalogued as rs192646888; called by muse, mutect2, varscan2
- ADGRG2 | c.262+21A>T | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- ARID5A | c.*148A>G | 3'UTR (SNP) | VAF 22/135 reads (16%) | catalogued as rs933063703; called by muse, mutect2, varscan2
- DOCK4 | c.1066+42C>G | Intron (SNP) | VAF 59/303 reads (19%) | called by muse, mutect2, varscan2
- IMMT | c.1032+14_1032+15insC | Intron (INS) | VAF 17/132 reads (13%) | called by mutect2, pindel, varscan2
- MDH2 | c.-5C>A | 5'UTR (SNP) | VAF 24/380 reads (6%) | called by muse, mutect2
- NLRP12 | c.2244-150G>A | Intron (SNP) | VAF 4/33 reads (12%) | catalogued as rs1484654494; called by muse, mutect2
- RPS3A | c.355-798dup | Intron (INS) | VAF 23/111 reads (21%) | called by mutect2, pindel, varscan2
